Somatic mutation profile of tumor specimen TCGA-4Z-AA7W-01A (aliquot TCGA-4Z-AA7W-01A-11D-A391-08) from TCGA case TCGA-4Z-AA7W, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 55.9 years (20,424 days).
Specimen TCGA-4Z-AA7W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb1849fb-7e0c-40ad-8d6c-55ae76d0f16d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7W-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7W-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5c1a1db-76f0-4760-894e-d3a50214f100

The open-access MAF lists 594 somatic variants for this specimen: 463 protein-altering or splice-affecting, 120 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 401, Silent 120, Nonsense Mutation 41, Splice Site 7, Intron 5, Frame Shift Del 5, Splice Region 3, In Frame Del 2, Frame Shift Ins 2, 5'UTR 2, 3'Flank 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RIT1 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1268A>G p.Q423R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV70037959; called by muse, mutect2, varscan2
- AC008397.2 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV53206284, COSV99441114, COSV99442346; called by muse, mutect2, varscan2
- AC023055.1 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60243944; called by muse, mutect2, varscan2
- ACACB | c.6984G>C p.W2328C | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58141054; called by muse, mutect2, varscan2
- ACAD10 | c.668G>C p.R223T | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV58160267; called by muse, varscan2
- ACTA2 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.606); catalogued as COSV56517443; called by muse, mutect2, varscan2
- ACVR2B | c.1006G>C p.V336L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61701520, COSV61703135, COSV61703800; called by muse, mutect2, varscan2
- ADAM11 | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52348295; called by muse, mutect2, varscan2
- ADAM8 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101291585, COSV69865041; called by muse, mutect2, varscan2
- ADCY10 | c.4345C>A p.L1449I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749690491, COSV63239583, COSV63240944, COSV63245296; called by muse, mutect2, varscan2
- ADH7 | c.602T>G p.V201G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52922219; called by mutect2, varscan2
- ADIG | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100972562; called by muse, varscan2
- ADIPOR1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV100579648; called by muse, mutect2
- ADRM1 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53366250; called by muse, mutect2
- AHNAK | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.168); catalogued as rs753417086, COSV57222962; called by muse, mutect2, varscan2
- AHNAK2 | c.12691C>T p.L4231F | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as rs745985994, COSV60923298; called by muse, mutect2, varscan2
- AKAP12 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53579112; called by muse, mutect2, varscan2
- AKAP9 | c.4685G>C p.R1562T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV62353128; called by muse, mutect2, varscan2
- AKR1D1 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV54339138; called by muse, mutect2
- AMER3 | c.541G>T p.G181W | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1180734866, COSV58468577; called by muse, mutect2, varscan2
- ANK1 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV55889009; called by muse, mutect2, varscan2
- ANKLE2 | c.641-1G>C p.X214_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV61709914; called by muse, mutect2, varscan2
- ANO4 | c.1399G>A p.E467K (on ENST00000392977 / NM_001286615.2; = p.E432K on NM_178826.4) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as rs1323040759, COSV54605819; called by muse, mutect2, varscan2
- ANTXR2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs762963168, COSV56317860; called by muse, mutect2, varscan2
- AOAH | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51746756, COSV51748031; called by muse, mutect2, varscan2
- AP2A2 | c.1408A>C p.N470H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59962590; called by muse, mutect2, varscan2
- ARHGEF11 | c.3989G>T p.G1330V | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59356506; called by muse, mutect2
- ARHGEF16 | c.1176-1G>A p.X392_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV65682698; called by mutect2, varscan2
- ARMCX6 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV62680844; called by muse, mutect2, varscan2
- ARNTL2 | c.1311C>G p.F437L | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV53827717; called by muse, mutect2
- ARRDC2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV55844819; called by muse, mutect2, varscan2
- ARRDC2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99716994; called by muse, mutect2, varscan2
- ARSK | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs368795148; called by muse, mutect2, varscan2
- ASB15 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51925706, COSV51928023; called by muse, mutect2, varscan2
- ASCC3 | c.2734G>C p.E912Q | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61231460; called by muse, mutect2, varscan2
- ASCC3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61231464; called by muse, mutect2, varscan2
- ASH1L | c.4306C>G p.P1436A | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as COSV64211213; called by muse, mutect2, varscan2
- ASXL2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55456149; called by muse, mutect2, varscan2
- ATP2B4 | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100397710, COSV58181386; called by muse, mutect2, varscan2
- ATRIP | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV56497620; called by muse, mutect2, varscan2
- BAZ2A | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV51640572; called by muse, mutect2, varscan2
- BCAT1 | c.584C>G p.S195* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV53913718, COSV99679068; called by muse, mutect2, varscan2
- BCL11B | c.1336C>T p.R446W (on ENST00000357195 / NM_001282237.2; = p.R375W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61737647; called by muse, mutect2
- BICD2 | c.1038G>C p.Q346H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV63550175; called by muse, mutect2
- BLID | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV73340318; called by muse, mutect2, varscan2
- BMP7 | c.1140G>C p.Q380H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213572809, COSV67781777; called by muse, mutect2, varscan2
- BPIFB6 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs762158268, COSV100848484, COSV62756097; called by muse, mutect2, varscan2
- BRCA2 | c.1947G>C p.Q649H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV66458718; called by muse, mutect2, varscan2
- BRCA2 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV66450764; called by muse, varscan2
- BRCA2 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs979372317, COSV66448966, COSV66451123, COSV66458736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66458745, COSV66462210; called by muse, mutect2, varscan2
- BSN | c.3301G>C p.E1101Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316957364, COSV56516255, COSV56521990, COSV56523589; called by muse, mutect2, varscan2
- BTN3A3 | c.996G>T p.W332C | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55072899; called by muse, mutect2
- C10orf90 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52965503; called by muse, mutect2, varscan2
- C12orf4 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 17/137 reads (12%) | catalogued as COSV99712978; called by muse, mutect2, varscan2
- C16orf70 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); catalogued as COSV54628508; called by muse, mutect2, varscan2
- C1orf162 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV100636169, COSV100636251; called by muse, mutect2
- C4BPA | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as rs762579470, COSV65537047; called by muse, mutect2, varscan2
- C5orf38 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV57412604; called by muse, mutect2, varscan2
- C7orf26 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100254105; called by muse, mutect2
- C8orf76 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52691194; called by muse, mutect2
- C9orf153 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV100188786; called by muse, mutect2, varscan2
- CACNG4 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV50926482; called by muse, mutect2, varscan2
- CATSPERE | c.1629C>G p.F543L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63680163; called by muse, mutect2, varscan2
- CBWD2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV52075681; called by muse, mutect2, varscan2
- CCDC110 | c.1153C>A p.L385I | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV56872504; called by muse, mutect2, varscan2
- CCNA2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as COSV52658301; called by muse, mutect2
- CCND1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV57122433; called by muse, mutect2, varscan2
- CCT2 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.046); catalogued as COSV54740941; called by muse, mutect2
- CD200R1 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99867893; called by muse, mutect2
- CDS1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55689679; called by muse, mutect2
- CEACAM6 | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 93/253 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52268430; called by muse, mutect2, varscan2
- CEMIP | c.2049C>G p.I683M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV54997125; called by muse, mutect2, varscan2
- CEP76 | c.1718C>G p.S573* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100043034; called by muse, mutect2, varscan2
- CFAP47 | c.4525C>G p.H1509D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57975413; called by muse, mutect2, varscan2
- CFAP61 | c.443C>G p.S148* | Nonsense Mutation (SNP) | VAF 13/161 reads (8%) | catalogued as COSV99846196; called by muse, mutect2
- CFL1 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV57380881; called by muse, mutect2, varscan2
- CHD4 | c.1117G>A p.D373N (on ENST00000357008 / NM_001363606.2; = p.D386N on NM_001273.5) | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58901600, COSV58906983; called by muse, mutect2
- CIT | c.3652C>G p.Q1218E | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55876731; called by muse, mutect2, varscan2
- CLCN2 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55603021; called by muse, mutect2, varscan2
- CLHC1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV68464594; called by muse, mutect2, varscan2
- CLPSL2 | c.273G>C p.L91F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.503); catalogued as COSV100846329; called by muse, mutect2
- CNTLN | c.2377A>C p.N793H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.244); catalogued as COSV52088622; called by muse, mutect2, varscan2
- CNTNAP1 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV52852635; called by muse, mutect2, varscan2
- COG6 | c.644T>C p.M215T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62997263; called by muse, mutect2, varscan2
- COL14A1 | c.5071G>A p.E1691K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1303715726, COSV52862324; called by muse, mutect2, varscan2
- COPA | c.3388G>C p.E1130Q | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV54106643; called by muse, mutect2, varscan2
- CPD | c.3646C>T p.H1216Y | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV56714689; called by muse, mutect2
- CRIM1 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs1368118516, COSV54869197; called by muse, varscan2
- CRIM1 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV54869207; called by muse, varscan2
- CRYBG3 | c.7732G>C p.E2578Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as COSV51714332; called by muse, mutect2, varscan2
- CSRNP3 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.134); catalogued as COSV58782816; called by muse, mutect2
- CTR9 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV100797543; called by muse, mutect2
- CUBN | c.9181G>A p.D3061N | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64722432; called by muse, mutect2, varscan2
- CYGB | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.299); catalogued as rs1349628825, COSV53150874; called by muse, mutect2, varscan2
- DCC | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs201581144, COSV100503374; called by muse, mutect2, varscan2
- DCHS1 | c.6859G>C p.E2287Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55039646; called by muse, mutect2, varscan2
- DDX60L | c.5051A>T p.Q1684L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99488591; called by muse, mutect2, varscan2
- DENND4C | c.2175G>C p.L725F | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV100991560, COSV66822873; called by muse, mutect2, varscan2
- DHTKD1 | c.293del p.G98Dfs*9 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | catalogued as rs781305913; called by mutect2, pindel, varscan2
- DNAH1 | c.11517C>G p.F3839L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs1197881249, COSV56238062; called by muse, mutect2, varscan2
- DNAH5 | c.12548C>A p.P4183H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54241110; called by muse, mutect2, varscan2
- DNAH5 | c.5554G>A p.D1852N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV54241120; called by muse, mutect2, varscan2
- DOCK4 | c.4972A>G p.T1658A | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as COSV70240667; called by muse, mutect2, varscan2
- DPEP3 | c.1233G>T p.V411= | Splice Region (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99262928; called by muse, mutect2
- DPH2 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV52544338; called by muse, mutect2, varscan2
- DPY19L3 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as COSV60478704; called by muse, mutect2, varscan2
- DQX1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52046704; called by muse, mutect2, varscan2
- DSEL | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59493441; called by muse, mutect2, varscan2
- DTNB | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV56481172; called by muse, mutect2, varscan2
- DTWD1 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99233793; called by muse, mutect2, varscan2
- DYRK4 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV50542312; called by muse, mutect2, varscan2
- EHMT2 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1562491928, COSV64997205; called by muse, mutect2, varscan2
- EIF2B4 | c.416C>G p.S139* (on ENST00000347454 / NM_001034116.2; = p.S138* on NM_015636.3) | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV52010444, COSV99278039; called by muse, mutect2, varscan2
- EIF2B5 | c.1166C>G p.P389R (on ENST00000647909; = p.P381R on NM_003907.3) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV56605586; called by muse, mutect2, varscan2
- EIF2B5 | c.1549G>T p.E517* (on ENST00000647909; = p.E509* on NM_003907.3) | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99889548; called by muse, mutect2, varscan2
- EIF2B5 | c.1630G>A p.E544K (on ENST00000647909; = p.E536K on NM_003907.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV56605595; called by muse, mutect2, varscan2
- EIF3A | c.2792G>C p.R931T | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1305182255, COSV64962440; called by muse, mutect2, varscan2
- EIPR1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs765955994, COSV66131650; called by muse, mutect2, varscan2
- EMID1 | c.466-1G>C p.X156_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as COSV61830294, COSV61830526; called by muse, mutect2, varscan2
- ENAH | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV52867731, COSV52870463; called by muse, mutect2, varscan2
- EPHB6 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1434624992, COSV67420027; called by muse, mutect2, varscan2
- EQTN | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV66219196; called by muse, mutect2, varscan2
- ERP29 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.079); catalogued as COSV99923724; called by muse, mutect2
- EXD1 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as COSV59253288, COSV59255551; called by muse, mutect2, varscan2
- EXO5 | c.1008C>A p.D336E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV56416200; called by muse, mutect2
- EXO5 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV56416212; called by muse, mutect2, varscan2
- EXOC8 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV50478912; called by muse, mutect2, varscan2
- FAM13A | c.2324C>G p.S775C | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52008632; called by muse, mutect2, varscan2
- FAM83G | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58760350; called by muse, mutect2, varscan2
- FAT4 | c.3529T>C p.F1177L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV101272909; called by muse, mutect2
- FBXO34 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV58255919; called by muse, mutect2, varscan2
- FBXO43 | c.1398C>G p.F466L | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV71054899; called by muse, mutect2, varscan2
- FBXO43 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV71054912; called by muse, mutect2, varscan2
- FGF14 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65951437; called by muse, mutect2, varscan2
- FGF22 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51261121; called by muse, varscan2
- FLG | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as COSV64243385, COSV64245208; called by muse, mutect2
- FLNB | c.4663C>T p.Q1555* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as COSV99915191; called by muse, mutect2, varscan2
- FLOT1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV64508780; called by muse, mutect2, varscan2
- FMO3 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV63007996; called by muse, mutect2
- FOXD4L1 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99380878; called by muse, mutect2, varscan2
- FOXM1 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs555339805, COSV100700869, COSV61206889; called by muse, mutect2, varscan2
- FRYL | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51940875, COSV51955003; called by muse, mutect2, varscan2
- FRYL | c.1816G>C p.D606H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV51947084, COSV51950581, COSV51955022; called by muse, mutect2, varscan2
- FYCO1 | c.1791G>C p.E597D | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56118016; called by muse, mutect2, varscan2
- FZD4 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV72294583; called by muse, mutect2, varscan2
- GAS2L2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782529922; called by muse, mutect2, varscan2
- GIGYF1 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV51944908; called by muse, mutect2, varscan2
- GIP | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV62467527; called by muse, mutect2, varscan2
- GNL2 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757122063, COSV66081263; called by muse, mutect2, varscan2
- GNRH1 | c.142-1G>C p.X48_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99373701; called by muse, mutect2
- GOLPH3L | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV55047095; called by muse, mutect2
- GPR158 | c.1959G>C p.L653F | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV66265415, COSV66277187; called by muse, mutect2, varscan2
- GPR37 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV58258603; called by muse, mutect2, varscan2
- GRIA3 | c.1954C>G p.L652V | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52072613; called by muse, mutect2, varscan2
- GRIK5 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53482460; called by muse, mutect2, varscan2
- GRIN2D | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54377459, COSV54381005; called by muse, varscan2
- GSC | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV53077503, COSV53077677; called by muse, mutect2, varscan2
- GSG1 | c.58T>C p.S20P (on ENST00000651961 / NM_001080555.4; = p.S7P on NM_031289.5) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60972461; called by muse, mutect2, varscan2
- GSTA1 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV58016252; called by muse, mutect2, varscan2
- GSTT2B | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1285888925; called by muse, mutect2
- H2BU1 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64209960; called by muse, mutect2, varscan2
- H3C3 | c.121C>A p.R41S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV63551301, COSV63551317; called by muse, mutect2, varscan2
- HAUS6 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1017175517, COSV65840447; called by muse, mutect2, varscan2
- HIVEP2 | c.3497C>T p.S1166F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1195260860, COSV50029958; called by muse, mutect2, varscan2
- HIVEP2 | c.3072G>C p.Q1024H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV50030083; called by muse, mutect2, varscan2
- HIVEP2 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1005845873, COSV50030169; called by muse, mutect2, varscan2
- HLA-G | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV64406367; called by muse, mutect2, varscan2
- HNRNPA1 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52937907; called by muse, mutect2, varscan2
- HNRNPA1 | c.290G>C p.R97T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV52937913; called by muse, mutect2, varscan2
- HOMEZ | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62537544; called by muse, mutect2, varscan2
- HOXA2 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV99761439; called by muse, mutect2, varscan2
- IARS2 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56962107; called by muse, mutect2, varscan2
- IFNA1 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV52806838; called by muse, mutect2, varscan2
- IGF2BP1 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.155); catalogued as COSV51733929, COSV99288975; called by muse, mutect2, varscan2
- IGF2BP3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV104385103, COSV51689631; called by muse, mutect2, varscan2
- IGHA2 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs1555452982; called by muse, mutect2, varscan2
- IGSF10 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs773485253, COSV56789083; called by muse, mutect2, varscan2
- IL17RD | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV56341000; called by muse, mutect2
- IL33 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67343421; called by muse, mutect2, varscan2
- INSR | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100253696; called by muse, mutect2
- IPO7 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100797859; called by muse, mutect2
- ITGAE | c.2265G>C p.W755C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53997315, COSV53998386; called by muse, mutect2, varscan2
- ITGAL | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63323462; called by muse, mutect2, varscan2
- ITIH1 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755213523, COSV56253654, COSV56257141; called by muse, mutect2, varscan2
- JADE1 | c.1631C>G p.S544C | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV56908056; called by muse, mutect2
- KANSL1 | c.1301C>G p.S434* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV99295008, COSV99295107; called by muse, mutect2, varscan2
- KATNA1 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV59503458; called by muse, mutect2, varscan2
- KHNYN | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs776675791, COSV52160014; called by muse, mutect2, varscan2
- KIAA0232 | c.2614C>G p.Q872E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV56927517; called by muse, mutect2, varscan2
- KIAA0319L | c.2239C>T p.H747Y | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57848364; called by muse, mutect2
- KIAA1109 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV52684613; called by muse, mutect2, varscan2
- KIF5A | c.2744C>G p.S915C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV54057100, COSV99673326; called by muse, mutect2, varscan2
- KIFBP | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as COSV62832109; called by muse, mutect2, varscan2
- KLF7 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV58745426; called by muse, varscan2
- KLHDC1 | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV100833639; called by muse, mutect2
- KLHL11 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as COSV59862632; called by muse, mutect2, varscan2
- KMT2A | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 51/112 reads (46%) | catalogued as COSV100630045; called by muse, mutect2, varscan2
- KNTC1 | c.3847C>T p.L1283F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as rs1400807960, COSV61082328; called by muse, mutect2, varscan2
- KPRP | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64222419; called by muse, mutect2, varscan2
- KRCC1 | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV61251919; called by muse, mutect2, varscan2
- KRCC1 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV61251923; called by muse, mutect2, varscan2
- KRT39 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV62917733, COSV62917880; called by muse, mutect2, varscan2
- LCE5A | c.118T>A p.C40S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.139); catalogued as COSV57501184; called by muse, mutect2
- LDB3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV53946369; called by muse, mutect2, varscan2
- LEPR | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62750166; called by muse, mutect2, varscan2
- LHCGR | c.653T>A p.F218Y | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54300656; called by muse, mutect2, varscan2
- LRIF1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV63896890, COSV63897061; called by muse, mutect2, varscan2
- LRRC31 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52982043; called by muse, mutect2, varscan2
- LRRC31 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.48); catalogued as COSV52982056; called by muse, mutect2, varscan2
- LYRM4 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV57993888; called by muse, mutect2
- MACC1 | c.1798G>T p.G600* | Nonsense Mutation (SNP) | VAF 20/176 reads (11%) | catalogued as COSV100256341; called by muse, mutect2, varscan2
- MAF | c.893A>C p.N298T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100392012; called by muse, mutect2
- MAP3K13 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53983368, COSV53993277; called by muse, mutect2, varscan2
- MAP3K13 | c.2569G>C p.D857H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53993300, COSV99406449; called by muse, mutect2, varscan2
- MARCHF10 | c.1384C>G p.P462A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV60889406; called by muse, mutect2, varscan2
- MARK1 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100857531, COSV65069774; called by muse, mutect2, varscan2
- MAST1 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV52251185; called by muse, mutect2, varscan2
- MBTPS1 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV58570475, COSV58571565; called by muse, mutect2, varscan2
- MCC | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV68728903; called by muse, mutect2, varscan2
- MCM10 | c.1369G>C p.D457H (on ENST00000484800 / NM_182751.3; = p.D456H on NM_018518.5) | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66335795; called by muse, mutect2, varscan2
- MCM3AP | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV52443182; called by muse, mutect2, varscan2
- MCM3AP | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV52443195; called by muse, mutect2
- MEF2B | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV50768012, COSV50776061; called by muse, mutect2
- MEFV | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs763288390, COSV54825227; called by muse, mutect2, varscan2
- MERTK | c.2685G>C p.L895F | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV54932985; called by muse, mutect2, varscan2
- METAP2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV54150082; called by muse, mutect2, varscan2
- MFSD2B | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57855595; called by muse, mutect2, varscan2
- MSRB2 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774911226, COSV64737779; called by muse, mutect2
- MTF1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.912); catalogued as rs1171697316, COSV65989962; called by muse, mutect2, varscan2
- MUC16 | c.39268C>G p.Q13090E | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746091142, COSV66694898; called by muse, mutect2, varscan2
- MUC7 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs149873135, COSV59217336; called by muse, mutect2
- MXD1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV52480402; called by muse, mutect2, varscan2
- MYO1F | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763029152, CM090125, COSV100596545, COSV57792734; called by muse, mutect2, varscan2
- NCOA2 | c.1412C>G p.S471* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV101476066; called by muse, mutect2, varscan2
- NCOR1 | c.6322C>T p.Q2108* | Nonsense Mutation (SNP) | VAF 42/132 reads (32%) | catalogued as COSV51980047; called by muse, mutect2, varscan2
- NDRG4 | c.347G>A p.G116E (on ENST00000570248 / NM_001378344.1; = p.G148E on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50749665; called by muse, mutect2
- NDUFAF3 | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV58246337, COSV58246741; called by muse, mutect2, varscan2
- NEK1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV71457393; called by muse, mutect2
- NELL1 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54297905; called by muse, mutect2, varscan2
- NEO1 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV56075512; called by muse, mutect2, varscan2
- NKD2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.402); catalogued as COSV56893659; called by muse, mutect2
- NLRP8 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV52585006, COSV52591140; called by muse, mutect2, varscan2
- NOTCH4 | c.2963G>C p.G988A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100901135; called by muse, mutect2
- NOXA1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV100395750; called by muse, mutect2
- NR2C1 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV58011385; called by muse, mutect2, varscan2
- NRCAM | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV61043734; called by muse, mutect2, varscan2
- NRXN3 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV73586295; called by muse, mutect2, varscan2
- NWD1 | c.2780C>G p.S927C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60338103, COSV60347347; called by muse, mutect2
- OBSCN | c.3629C>G p.S1210* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99472314; called by muse, mutect2, varscan2
- OBSCN | c.3742C>G p.Q1248E | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.038); catalogued as COSV52803562; called by muse, mutect2, varscan2
- OGDH | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56054159; called by muse, mutect2, varscan2
- OGDHL | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65103745; called by muse, mutect2, varscan2
- OPA1 | c.2239G>C p.E747Q (on ENST00000361510 / NM_130837.3; = p.E692Q on NM_015560.3) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as COSV62482219, COSV62483352; called by muse, mutect2, varscan2
- OR11L1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100869478, COSV63315144; called by muse, mutect2, varscan2
- OR2T12 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.119); catalogued as COSV58778631; called by muse, mutect2, varscan2
- OR51A7 | c.422T>A p.V141D | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63788706; called by muse, mutect2, varscan2
- OR5M1 | c.922A>C p.K308Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV73202290; called by muse, mutect2, varscan2
- OSBPL5 | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV55143953; called by muse, mutect2, varscan2
- OSR1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs771434319, COSV55346032; called by muse, mutect2, varscan2
- OSR2 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1424370627, COSV52558115; called by muse, mutect2, varscan2
- OSR2 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV52558136; called by muse, mutect2, varscan2
- OTOF | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.272); catalogued as rs747492513, COSV55514081; called by mutect2, varscan2
- PBX2 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV66709177; called by muse, mutect2, varscan2
- PCDHGA12 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV52759715; called by muse, mutect2, varscan2
- PCSK9 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56163222, COSV56163552; called by muse, mutect2, varscan2
- PDE5A | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as rs1413255808, COSV53350854; called by muse, mutect2, varscan2
- PDGFRA | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 40/148 reads (27%) | catalogued as COSV57275757, COSV99957846; called by muse, mutect2, varscan2
- PDLIM5 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100524427; called by muse, mutect2, varscan2
- PHTF2 | c.135C>G p.F45L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.418); catalogued as COSV99302443; called by muse, mutect2
- PIWIL1 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV55347272; called by muse, mutect2, varscan2
- PKP2 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV50739326; called by muse, mutect2
- PKP2 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1360804472, COSV50739383; called by muse, mutect2, varscan2
- PLCL2 | c.1048C>A p.Q350K (on ENST00000615277 / NM_001144382.2; = p.Q224K on NM_015184.5) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV67623904; called by muse, mutect2
- PLCL2 | c.2855C>A p.S952Y (on ENST00000615277 / NM_001144382.2; = p.S826Y on NM_015184.5) | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV67623906; called by muse, mutect2, varscan2
- PLEKHG4B | c.1199C>G p.P400R (on ENST00000283426; = p.P756R on NM_052909.5) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.246); catalogued as COSV52051725; called by muse, mutect2
- PLEKHO2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772552574, COSV60262565; called by muse, mutect2, varscan2
- PLRG1 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57424272; called by muse, mutect2, varscan2
- PNMA5 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as rs1556924555, COSV100721554; called by muse, mutect2, varscan2
- POGLUT2 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs764684810, COSV99959140; called by muse, mutect2, varscan2
- POLH | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV64780433; called by muse, mutect2, varscan2
- POLR1C | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV54832971; called by muse, mutect2, varscan2
- PRAM1 | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV55315535; called by muse, mutect2
- PRF1 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV64615527; called by muse, mutect2
- PRIMPOL | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV59249793; called by muse, mutect2, varscan2
- PRPF40B | c.586C>G p.Q196E (on ENST00000380281; = p.Q190E on NM_012272.3) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.217); catalogued as COSV56060812, COSV56062131; called by muse, mutect2
- PRPF40B | c.1861G>A p.E621K (on ENST00000380281; = p.E608K on NM_012272.3) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53305334; called by muse, mutect2, varscan2
- PRRC2A | c.5777C>G p.S1926C | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV52993244; called by muse, mutect2
- PRX | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV52532060; called by muse, mutect2, varscan2
- PSMD9 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV55840264; called by muse, mutect2, varscan2
- PTPN13 | c.2518G>C p.D840H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1323670341; called by mutect2, varscan2
- PTPN9 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV60725120; called by muse, mutect2
- PTPRT | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 133/477 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.088); catalogued as COSV61962187, COSV62002289; called by muse, mutect2, varscan2
- RAB34 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV99973146; called by muse, mutect2
- RANBP2 | c.4943C>G p.S1648* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV99313458; called by muse, varscan2
- RASAL2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62718727; called by muse, mutect2, varscan2
- RASGRF1 | c.3178G>C p.E1060Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV67250744; called by muse, mutect2, varscan2
- RBBP6 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV60507251; called by muse, mutect2, varscan2
- RCAN1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV100571728; called by muse, mutect2
- RCCD1 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1006815086, COSV67793822; called by muse, mutect2, varscan2
- RFTN1 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1406936501, COSV61921363; called by muse, mutect2
- RFX4 | c.1102G>C p.D368H (on ENST00000392842 / NM_213594.3; = p.D274H on NM_032491.6) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57578628, COSV99986264; called by muse, mutect2, varscan2
- RIC8B | c.128G>C p.R43T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV62696055; called by muse, mutect2, varscan2
- RIF1 | c.5068G>C p.D1690H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV54621099; called by muse, mutect2, varscan2
- RIMS2 | c.3325C>T p.L1109F (on ENST00000666250 / NM_001348490.2; = p.L917F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51703872; called by muse, mutect2, varscan2
- RLF | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.051); catalogued as COSV65652596; called by muse, mutect2, varscan2
- RNASE9 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV58880817; called by muse, mutect2, varscan2
- RNF130 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56149579, COSV56152208; called by muse, mutect2, varscan2
- RPL34 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs747070938, COSV67135608; called by muse, mutect2
- RPN1 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); catalogued as COSV56190990; called by muse, mutect2, varscan2
- RPN1 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56191000; called by muse, mutect2, varscan2
- RPS6KL1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs148351182; called by muse, mutect2, varscan2
- RPTOR | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100157469, COSV60809827, COSV60813916; called by muse, mutect2, varscan2
- RRN3 | c.446G>C p.S149T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.317); catalogued as rs1193519815, COSV99549160; called by muse, mutect2, varscan2
- SAMD15 | c.1926G>C p.L642F | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53630077; called by muse, mutect2, varscan2
- SAMD4A | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV51880573, COSV51885324; called by muse, mutect2, varscan2
- SAMD7 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59419554; called by muse, mutect2, varscan2
- SCAF8 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.205); catalogued as COSV65793038; called by muse, mutect2, varscan2
- SCN10A | c.3843C>G p.I1281M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71862292, COSV71862642; called by muse, mutect2
- SDF2 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55932119; called by muse, varscan2
- SECISBP2 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV58686692; called by muse, mutect2, varscan2
- SERPINA1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs759578830, COSV63346090; called by muse, mutect2, varscan2
- SETDB1 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV54988952; called by muse, mutect2, varscan2
- SETX | c.5981C>G p.S1994C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.87); catalogued as rs1259820848, COSV56390266; called by muse, mutect2, varscan2
- SGCE | c.699C>G p.N233K (on ENST00000647096; = p.N197K on NM_003919.3) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.882); catalogued as COSV56018891; called by muse, mutect2, varscan2
- SGO2 | c.3704C>G p.S1235* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100764812; called by muse, mutect2, varscan2
- SIGLEC8 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs138700631; called by muse, mutect2, varscan2
- SLC1A7 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.071); catalogued as rs868705614, COSV100439538, COSV57015656; called by muse, mutect2, varscan2
- SLC22A6 | c.1397G>C p.R466P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100842881; called by muse, mutect2
- SLC25A27 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51495334, COSV51497762; called by muse, mutect2, varscan2
- SLC25A42 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV59381167; called by muse, mutect2, varscan2
- SLC26A3 | c.1166G>C p.R389T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV60641499; called by muse, mutect2, varscan2
- SLC29A2 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237226; called by muse, mutect2
- SLC29A4 | c.324G>C p.M108I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV51875795, COSV51876836; called by muse, mutect2
- SLC2A9 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.44); PolyPhen probably damaging (1); catalogued as COSV53325040, COSV53330323; called by muse, mutect2
- SLC35F4 | c.560T>G p.I187S (on ENST00000339762 / NM_001352015.2; = p.I151S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV60266058; called by muse, mutect2, varscan2
- SLC38A2 | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1018465383, COSV56745859; called by muse, mutect2, varscan2
- SLC38A2 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV56745868; called by muse, mutect2, varscan2
- SLC39A4 | c.1510G>A p.D504N (on ENST00000301305 / NM_001374839.1; = p.D479N on NM_017767.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554872303, COSV52780435, COSV99433140; called by mutect2, varscan2
- SLC4A8 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as COSV60656067; called by muse, mutect2, varscan2
- SLC5A5 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.394); catalogued as COSV99715385; called by muse, mutect2
- SLFNL1 | c.1198G>C p.V400L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57235227; called by muse, mutect2, varscan2
- SMARCA2 | c.2469C>G p.F823L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV61806370, COSV61810266; called by muse, mutect2, varscan2
- SORT1 | c.2298G>C p.L766F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV56668293; called by muse, mutect2, varscan2
- SOS1 | c.1981A>G p.I661V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1181488319, COSV67676671; called by muse, mutect2, varscan2
- SPATA12 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.422); catalogued as COSV57589869; called by muse, mutect2, varscan2
- SPEN | c.5203C>T p.P1735S | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65365319; called by muse, mutect2, varscan2
- SPTAN1 | c.2218C>G p.Q740E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as COSV63988749; called by muse, mutect2, varscan2
- SPTAN1 | c.2943G>C p.K981N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1441170050, COSV63988753; called by muse, mutect2, varscan2
- SPTAN1 | c.3267G>C p.K1089N | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63985590, COSV63988760; called by muse, mutect2, varscan2
- SREBF2 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63331993; called by muse, mutect2, varscan2
- SRGAP2 | c.1993G>C p.E665Q (on ENST00000624873 / NM_001170637.4; = p.E666Q on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.342); catalogued as COSV55337742; called by muse, mutect2, varscan2
- SRRM2 | c.2498A>G p.Q833R | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV57077706; called by muse, mutect2, varscan2
- SSX2IP | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100642768, COSV60552317; called by muse, mutect2, varscan2
- ST13 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53422818; called by muse, mutect2, varscan2
- STAC2 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.368); catalogued as COSV61065338, COSV61066245; called by muse, mutect2
- SUPT3H | c.661G>C p.E221Q (on ENST00000371460 / NM_181356.3; = p.E210Q on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV60945470; called by muse, mutect2, varscan2
- SWT1 | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs752114727; called by muse, mutect2, varscan2
- SYK | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as COSV65325529, COSV65329098; called by muse, mutect2, varscan2
- SYNE1 | c.8185G>C p.E2729Q (on ENST00000367255 / NM_182961.4; = p.E2736Q on NM_033071.3) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV55045595; called by muse, mutect2, varscan2
- SYNPO2 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61114434, COSV61114607; called by muse, mutect2, varscan2
- SYT5 | c.936C>G p.F312L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62830944; called by muse, mutect2, varscan2
- TAF1C | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as COSV100499818; called by muse, mutect2
- TBK1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1361172917, COSV59157083; called by muse, mutect2
- TC2N | c.638-1G>C p.X213_splice | Splice Site (SNP) | VAF 7/93 reads (8%) | catalogued as COSV61747745; called by muse, mutect2
- TCF4 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61890439; called by muse, mutect2
- TCHH | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs879100208, COSV64276399; called by muse, varscan2
- TCHH | c.3051G>C p.E1017D | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV64276404; called by muse, varscan2
- TDRD6 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60173932, COSV60177173; called by muse, mutect2
- TENM1 | c.1580-1G>A p.X527_splice | Splice Site (SNP) | VAF 11/17 reads (65%) | catalogued as COSV100951141; called by muse, mutect2, varscan2
- TERT | c.612C>G p.N204K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV99721205; called by muse, mutect2
- TEX14 | c.1936C>G p.P646A (on ENST00000240361 / NM_001201457.2; = p.P640A on NM_031272.5) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV53622264; called by muse, mutect2, varscan2
- TEX55 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as COSV55212239, COSV55213027; called by muse, mutect2, varscan2
- TFAP2D | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as COSV99148089; called by muse, mutect2
- TFRC | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV64055775; called by muse, mutect2, varscan2
- TIGD4 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV58550336; called by muse, mutect2, varscan2
- TIGD5 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.847); catalogued as COSV57821565; called by muse, mutect2, varscan2
- TLE1 | c.1980C>T p.I660= | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as COSV64720778, COSV64722275; called by muse, mutect2, varscan2
- TMCC1 | c.1271C>G p.S424C (on ENST00000393238 / NM_001349268.2; = p.S100C on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61441926; called by muse, mutect2, varscan2
- TMEM131 | c.2453C>G p.S818* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99489757; called by muse, mutect2
- TMEM131 | c.2204C>G p.S735* | Nonsense Mutation (SNP) | VAF 49/204 reads (24%) | catalogued as COSV99489761, COSV99489905; called by muse, mutect2, varscan2
- TMEM209 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV61021678, COSV61023194; called by muse, mutect2, varscan2
- TMEM60 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243736653, COSV51896343, COSV99301363; called by muse, mutect2, varscan2
- TMIGD3 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV62728538; called by muse, mutect2, varscan2
- TMTC1 | c.479C>T p.A160V (on ENST00000539277 / NM_001193451.2; = p.A52V on NM_175861.3) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779339155, COSV55488366, COSV99758642; called by muse, mutect2, varscan2
- TMX3 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100218690, COSV55186579; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2403G>A p.M801I | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV64101892; called by muse, mutect2
- TOM1L1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61948706, COSV61949656; called by muse, mutect2, varscan2
- TOR1AIP1 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.192); catalogued as COSV54870903; called by muse, mutect2, varscan2
- TP53BP2 | c.2266C>T p.Q756* (on ENST00000343537 / NM_001031685.3; = p.Q627* on NM_005426.2) | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV100636836; called by muse, mutect2, varscan2
- TPP1 | c.713C>G p.S238* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as CM023616, COSV100197007; called by muse, mutect2
- TRIM10 | c.1445G>C p.*482Sext*34 | Nonstop Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as COSV100939719; called by muse, mutect2, varscan2
- TRIM45 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56714416; called by muse, varscan2
- TRIM45 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV56713692, COSV56714109; called by muse, varscan2
- TRIM69 | c.700G>C p.E234Q (on ENST00000329464 / NM_182985.5; = p.E75Q on NM_080745.5) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV57804704; called by muse, mutect2, varscan2
- TROAP | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV57745228; called by muse, mutect2, varscan2
- TROAP | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV57745240; called by muse, mutect2, varscan2
- TSFM | c.372G>C p.E124D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55744901; called by muse, mutect2, varscan2
- TTC31 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV52036492; called by muse, mutect2, varscan2
- TTC5 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV51871708; called by muse, mutect2, varscan2
- TTF2 | c.2118C>G p.N706K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs960856564, COSV65633246; called by muse, mutect2, varscan2
- TTLL4 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758463335, COSV51438163; called by muse, mutect2, varscan2
- TTN | c.75878C>T p.S25293L (on ENST00000591111; = p.S17869L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | PolyPhen benign (0.098); catalogued as COSV60215367; called by muse, mutect2, varscan2
- TTN | c.54205A>G p.S18069G (on ENST00000591111; = p.S10645G on NM_003319.4) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | PolyPhen benign (0); catalogued as COSV59879782, COSV60261661; called by muse, mutect2, varscan2
- TTN | c.47081G>A p.R15694H (on ENST00000591111; = p.R8270H on NM_003319.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | PolyPhen benign (0); catalogued as rs367603302, COSV60286751; ClinVar: likely benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- UCHL3 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.098); catalogued as COSV66460141; called by muse, mutect2, varscan2
- ULK2 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV64447243; called by muse, mutect2, varscan2
- UNC93B1 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57097599, COSV57100172, COSV57100967; called by muse, mutect2, varscan2
- UTP14A | c.84G>C p.L28F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV64100966, COSV64101995; called by muse, mutect2, varscan2
- UTP14A | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV64102001; called by muse, mutect2, varscan2
- VAC14 | c.546G>C p.E182D | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV55755990; called by muse, mutect2, varscan2
- VAMP8 | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1416347609, COSV55705592, COSV55705699; called by muse, mutect2, varscan2
- VILL | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV99379320; called by muse, mutect2
- VIPAS39 | c.1421C>G p.S474* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100493291; called by muse, mutect2
- VPS13B | c.2158C>G p.Q720E | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV62023190; called by muse, mutect2, varscan2
- VPS52 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1332208411, COSV71403569; called by muse, mutect2, varscan2
- WDR31 | c.622G>A p.E208K (on ENST00000374193 / NM_001006615.3; = p.E207K on NM_145241.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs918243300, COSV59147054; called by muse, mutect2, varscan2
- WDR45 | c.610G>T p.G204C (on ENST00000376372 / NM_001029896.2; = p.G205C on NM_007075.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59876526; called by muse, mutect2
- WDR46 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV65842692; called by muse, mutect2, varscan2
- WDR55 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as COSV56908413; called by muse, mutect2, varscan2
- WHAMM | c.1722G>C p.Q574H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV54498029; called by muse, mutect2, varscan2
- WNK4 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55907989; called by muse, mutect2, varscan2
- WNT4 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1300290034, COSV51604976, COSV99268692; called by muse, mutect2, varscan2
- WSCD1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV58496930; called by muse, mutect2, varscan2
- XPC | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53206785; called by muse, mutect2
- YIPF1 | c.603T>G p.I201M | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as COSV50778512; called by muse, mutect2, varscan2
- YME1L1 | c.1036G>T p.E346* (on ENST00000326799 / NM_139312.3; = p.E289* on NM_014263.4) | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100464302; called by muse, mutect2
- YPEL4 | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV55518915; called by muse, mutect2, varscan2
- ZBTB37 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs778197080, COSV62933739; called by muse, mutect2, varscan2
- ZBTB49 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); catalogued as rs775615710, COSV100552317, COSV61924550; called by mutect2, varscan2
- ZDHHC13 | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1425429616, COSV67981526; called by muse, mutect2, varscan2
- ZIC1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV51556104, COSV99291933; called by muse, mutect2, varscan2
- ZIC3 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54973037; called by muse, mutect2, varscan2
- ZMYND8 | c.2434C>A p.P812T (on ENST00000311275 / NM_001363741.2; = p.P832T on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.83); catalogued as rs771024245, COSV53692990; called by muse, mutect2, varscan2
- ZNF184 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV53004451, COSV53005098; called by muse, mutect2, varscan2
- ZNF229 | c.1743C>G p.F581L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037092346, COSV52163762; called by muse, mutect2, varscan2
- ZNF230 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV71273247, COSV71273586; called by muse, mutect2
- ZNF318 | c.6256G>C p.E2086Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as COSV58935204; called by muse, mutect2, varscan2
- ZNF366 | c.1206C>A p.F402L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376919588, COSV59216196, COSV59217612; called by mutect2, varscan2
- ZNF385B | c.963A>G p.G321= | Splice Region (SNP) | VAF 19/66 reads (29%) | catalogued as rs1276691405, COSV61179764; called by muse, mutect2, varscan2
- ZNF395 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60429682; called by muse, mutect2, varscan2
- ZNF460 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64416072; called by muse, mutect2, varscan2
- ZNF560 | c.2342C>G p.S781* | Nonsense Mutation (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100039091; called by muse, mutect2, varscan2
- ZNF721 | c.938G>A p.R313K (on ENST00000338977; = p.R325K on NM_133474.4) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.911); catalogued as COSV59089826, COSV59090695; called by muse, mutect2
- ZNF772 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV58411266; called by muse, mutect2, varscan2
- ZNF786 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100303028; called by muse, mutect2
- ZSCAN21 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV52851744; called by muse, mutect2, varscan2
- ABCA9 | c.95_96+8del p.X32_splice | Splice Site (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel
- AQP7 | c.937_954del p.P313_S318del | In Frame Del (DEL) | VAF 16/130 reads (12%) | called by pindel, varscan2
- CEP162 | c.3268_3278del p.L1090Tfs*51 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- DNTTIP2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2
- FLNB | c.4221del p.G1408Afs*8 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- IGKV3-11 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- KDM6A | c.1596dup p.L533Tfs*20 | Frame Shift Ins (INS) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- MRPS7 | c.558_561del p.W186* | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- OR2AK2 | c.269_277del p.K90_I92del | In Frame Del (DEL) | VAF 20/111 reads (18%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1251G>C p.E417D | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- RENBP | c.1107del p.F369Lfs*4 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- TRBC2 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- WNT5A | c.245dup p.C83Vfs*38 | Frame Shift Ins (INS) | VAF 20/131 reads (15%) | called by mutect2, pindel, varscan2
- ABCC5 | c.2625C>T p.F875= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs1348689936, COSV55593990; called by muse, mutect2, varscan2
- AC011462.1 | c.345C>G p.V115= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV54197934; called by muse, mutect2
- ACTB | c.30C>G p.V10= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs768066226, COSV59320045; called by mutect2, varscan2
- ADAM11 | c.2298C>A p.S766= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs373734841, COSV52348308; called by muse, mutect2, varscan2
- ADCY2 | c.435C>T p.F145= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs765777716, COSV57869101; called by muse, mutect2, varscan2
- AGO2 | c.1284G>A p.A428= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as rs559356764, COSV55050183; called by muse, mutect2, varscan2
- ALB | c.1704G>A p.L568= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs11538206, COSV55740259; called by muse, mutect2, varscan2
- ARHGAP19 | c.693C>T p.L231= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV100363210, COSV57394555; called by muse, mutect2, varscan2
- ARRDC5 | c.837G>A p.V279= (on ENST00000381781; = p.V265= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs761805228, COSV67788169; called by muse, mutect2, varscan2
- ART1 | c.585G>A p.V195= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51705943; called by muse, mutect2, varscan2
- ATP8B2 | c.2637C>T p.S879= (on ENST00000672630; = p.S846= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 81/338 reads (24%) | catalogued as COSV59247570; called by muse, mutect2, varscan2
- AVL9 | c.327C>A p.I109= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV59467717; called by muse, mutect2, varscan2
- B4GALT7 | c.930C>G p.L310= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1374861652, COSV50352831, COSV99219140; called by muse, varscan2
- BTG2 | c.300G>C p.L100= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV51857020; called by muse, mutect2, varscan2
- C12orf66 | c.718C>T p.L240= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100320685, COSV61322944, COSV61324099; called by muse, mutect2, varscan2
- CBLIF | c.222C>G p.L74= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV57239842; called by muse, mutect2
- CC2D2A | c.861C>T p.F287= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs1560159855, COSV67504853; called by muse, mutect2
- CD6 | c.1212C>T p.P404= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as COSV57840816; called by muse, mutect2, varscan2
- CDR2L | c.1362C>T p.I454= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100464779; called by muse, mutect2, varscan2
- CELSR1 | c.3822C>T p.F1274= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV53095472; called by muse, mutect2, varscan2
- CEP131 | c.2040C>G p.L680= (on ENST00000269392 / NM_001319228.2; = p.L677= on NM_014984.4) | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as rs768712461, COSV53954858; called by muse, mutect2, varscan2
- CFAP45 | c.291C>T p.P97= | Silent (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- CHST5 | c.123C>T p.T41= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV60340653; called by muse, mutect2, varscan2
- CLCN2 | c.852C>T p.F284= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV55603030, COSV55604257; called by muse, mutect2, varscan2
- CMYA5 | c.11676C>T p.L3892= | Silent (SNP) | VAF 55/168 reads (33%) | catalogued as COSV69745956; called by muse, mutect2, varscan2
- CNGB3 | c.942C>T p.Y314= | Silent (SNP) | VAF 65/187 reads (35%) | catalogued as COSV60694470; called by muse, mutect2, varscan2
- CNNM4 | c.546C>G p.L182= | Silent (SNP) | VAF 47/322 reads (15%) | catalogued as COSV65660646, COSV65661651; called by muse, mutect2, varscan2
- CNTN1 | c.1608C>T p.L536= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs532938180, COSV61637976; called by muse, mutect2, varscan2
- COL3A1 | c.1005T>A p.P335= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV58593522; called by muse, mutect2, varscan2
- CUL7 | c.4575C>G p.L1525= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV54819950; called by muse, mutect2, varscan2
- CXCL5 | c.252G>A p.L84= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV56018795; called by muse, mutect2, varscan2
- DAGLA | c.708C>T p.I236= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV57198229; called by muse, mutect2, varscan2
- DCTD | c.429C>G p.L143= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV63867115; called by muse, mutect2
- DDX60L | c.897C>T p.L299= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1331437029, COSV52718034; called by muse, mutect2, varscan2
- DYRK3 | c.1590C>G p.L530= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65607030; called by muse, mutect2, varscan2
- ECSIT | c.1179C>T p.L393= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV52940184; called by muse, mutect2, varscan2
- ENDOU | c.555C>T p.L185= (on ENST00000422538 / NM_001172439.2; = p.L144= on NM_006025.4) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99968395; called by muse, mutect2
- FOSB | c.897G>A p.S299= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV62279029; called by muse, mutect2, varscan2
- FOXL1 | c.321C>T p.F107= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs1419064702, COSV57214860; called by muse, mutect2, varscan2
- FREM1 | c.1428C>G p.L476= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV66527127; called by muse, mutect2, varscan2
- GAB1 | c.1998G>A p.K666= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV53758993; called by muse, mutect2, varscan2
- GABBR2 | c.2076C>T p.I692= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs141903124; ClinVar: likely benign; called by muse, mutect2, varscan2
- GK5 | c.744G>A p.V248= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101242353; called by muse, mutect2
- GLDC | c.375C>T p.S125= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs750281192, COSV58681444, COSV58682926; called by muse, mutect2, varscan2
- GP1BA | c.1920G>A p.L640= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs371435100; called by muse, mutect2, varscan2
- GPR161 | c.177C>T p.L59= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV54792634; called by muse, mutect2, varscan2
- GPS2 | c.630C>T p.L210= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs772367743, COSV59752034; called by muse, mutect2, varscan2
- GRIK5 | c.747C>T p.F249= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV53482440; called by muse, mutect2, varscan2
- HHIPL2 | c.1017C>A p.G339= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV58563571, COSV58566533; called by muse, mutect2, varscan2
- HSP90AA1 | c.621G>A p.V207= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1249248091, COSV99355553; called by muse, mutect2
- HSPA4L | c.120A>G p.S40= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as rs1273028542, COSV56547139; called by muse, mutect2, varscan2
- IGF1R | c.1842C>T p.P614= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV51293067; called by muse, mutect2, varscan2
- INTS5 | c.150C>G p.L50= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs752488137, COSV57952741; called by muse, mutect2, varscan2
- ITGA6 | c.3051C>T p.F1017= (on ENST00000442250; = p.F978= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV51236597; called by muse, mutect2, varscan2
- ITIH6 | c.3477C>T p.I1159= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs768497345, COSV54491666; called by muse, mutect2, varscan2
- ITPR2 | c.5562T>C p.D1854= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV101190211, COSV67275630; called by muse, mutect2
- KCNMA1 | c.867G>A p.L289= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV54269563; called by muse, mutect2, varscan2
- LAMA5 | c.4776C>G p.L1592= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1208206059, COSV53363611, COSV53366259; called by muse, mutect2, varscan2
- LGR4 | c.1317G>A p.L439= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV64865313; called by muse, mutect2, varscan2
- LRIT3 | c.960C>A p.S320= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs1383137135, COSV59986571; called by muse, mutect2, varscan2
- LRRC52 | c.168G>T p.R56= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV54231681, COSV54233061; called by muse, mutect2, varscan2
- LSAMP | c.423C>T p.V141= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV61303175; called by muse, mutect2, varscan2
- MAPT | c.2482C>T p.L828= (on ENST00000262410 / NM_001377265.1; = p.L436= on NM_005910.5) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV52244469; called by muse, mutect2, varscan2
- MED13 | c.4347C>G p.L1449= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs887077578, COSV67265559; called by muse, mutect2, varscan2
- MFSD14A | c.813C>G p.L271= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV64515001; called by muse, mutect2, varscan2
- MUL1 | c.1038G>A p.V346= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV51642566; called by muse, mutect2, varscan2
- MYOM2 | c.2838C>G p.S946= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs560428611, COSV50703027, COSV50742216; called by muse, mutect2, varscan2
- NCK1 | c.321C>G p.L107= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV56638804; called by muse, mutect2, varscan2
- NFKBIZ | c.1758G>A p.L586= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV58201332; called by muse, mutect2, varscan2
- NIM1K | c.852C>G p.L284= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100390365, COSV58144024; called by muse, mutect2
- NSD1 | c.7503G>T p.P2501= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs778042831, COSV61778893, COSV61780421; called by muse, mutect2, varscan2
- NSMCE2 | c.72C>G p.L24= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV54902240; called by muse, mutect2, varscan2
- OCA2 | c.2385G>C p.G795= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV62352661; called by muse, mutect2, varscan2
- OR1L6 | c.153C>G p.L51= (on ENST00000373684; = p.L15= on NM_001004453.2) | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV100490995, COSV59029221; called by muse, mutect2, varscan2
- OR52H1 | c.741C>G p.V247= (on ENST00000322653; = p.V253= on NM_001005289.1) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV59505292, COSV59505309, COSV59505935; called by muse, mutect2, varscan2
- PCDH17 | c.1065C>T p.S355= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV64976855; called by muse, mutect2, varscan2
- PCDHB15 | c.1449C>T p.N483= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs781919155, COSV51181964; called by muse, mutect2, varscan2
- PCLO | c.5958G>A p.Q1986= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as COSV61652382; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PDZRN4 | c.1818C>G p.L606= (on ENST00000402685 / NM_001164595.2; = p.L348= on NM_013377.4) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100113871, COSV54194642, COSV54210036; called by muse, mutect2, varscan2
- PITPNC1 | c.304C>T p.L102= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100084235; called by muse, mutect2
- PLEKHM2 | c.2931C>T p.L977= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs1471574740, COSV53817713; called by muse, mutect2, varscan2
- PLSCR4 | c.717G>A p.K239= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV61608663; called by muse, mutect2, varscan2
- POTEE | c.60C>T p.L20= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as rs1559167916, COSV58237887; called by muse, mutect2, varscan2
- PRCP | c.1023G>A p.V341= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs776739719, COSV57290190; called by muse, mutect2, varscan2
- PRKAG2 | c.393C>G p.S131= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV55235657; called by muse, mutect2, varscan2
- PTMS | c.97C>A p.R33= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV52568579; called by muse, mutect2, varscan2
- PTPMT1 | c.336G>A p.Q112= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1399191250, COSV58597524; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2760G>A p.V920= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV54762368; called by muse, mutect2, varscan2
- RAB26 | c.741G>A p.E247= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs767749416, COSV52954991; called by muse, mutect2, varscan2
- RAB9A | c.216G>C p.L72= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV54611062; called by muse, mutect2, varscan2
- RHOU | c.633C>T p.L211= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as rs906428984, COSV64208862; called by muse, mutect2
- RNF186 | c.201G>A p.L67= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV64296865; called by muse, mutect2, varscan2
- SF3A1 | c.2127C>G p.V709= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV53170251; called by muse, mutect2, varscan2
- SH2D3C | c.2532C>T p.L844= (on ENST00000314830 / NM_170600.3; = p.L687= on NM_005489.4) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100137672; called by muse, mutect2
- SI | c.2259G>A p.V753= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV52290846; called by muse, mutect2, varscan2
- SIX1 | c.150C>G p.L50= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs763114674, COSV55960550; called by muse, mutect2, varscan2
- SLC13A5 | c.201C>T p.F67= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs900258843, COSV53424248; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC2A10 | c.1608G>A p.E536= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV63715553; called by muse, mutect2
- SLC44A4 | c.999G>A p.R333= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs1348180529, COSV57669254; called by muse, mutect2, varscan2
- SLC4A1AP | c.516G>T p.L172= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV58136396; called by muse, mutect2, varscan2
- SMAD3 | c.807C>T p.F269= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV59287364; called by muse, mutect2, varscan2
- SMAD3 | c.1089C>T p.V363= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV59287385; called by muse, mutect2, varscan2
- SPTAN1 | c.1863C>T p.L621= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV63988746; called by muse, mutect2, varscan2
- SZT2 | c.183C>T p.L61= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV60290577; called by muse, mutect2, varscan2
- TCTE1 | c.384G>A p.E128= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV65256004; called by muse, mutect2, varscan2
- TECTA | c.366G>A p.L122= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV50757519; called by muse, mutect2
- TEX55 | c.675G>A p.Q225= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV55212231; called by muse, mutect2, varscan2
- TLR8 | c.2214G>C p.L738= (on ENST00000218032 / NM_138636.5; = p.L756= on NM_016610.4) | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV54319459, COSV99487043; called by muse, mutect2, varscan2
- TOX2 | c.1410G>A p.E470= (on ENST00000358131 / NM_001098798.2; = p.E446= on NM_032883.3) | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs772155811, COSV57891472; called by muse, mutect2, varscan2
- TRAIP | c.1137G>A p.E379= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58915654; called by muse, mutect2, varscan2
- TRMT61B | c.264C>T p.L88= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV60258582; called by muse, mutect2, varscan2
- TRPM6 | c.621C>T p.I207= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs749287479, COSV62502142; called by muse, mutect2, varscan2
- TSHZ3 | c.1962C>T p.I654= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1370806640, COSV53674574, COSV53677582; called by mutect2, varscan2
- TTC29 | c.1062G>C p.V354= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV57280678; called by muse, mutect2, varscan2
- WDCP | c.294C>T p.S98= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV54593132; called by muse, mutect2, varscan2
- WDR45 | c.609A>C p.P203= (on ENST00000376372 / NM_001029896.2; = p.P204= on NM_007075.3) | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV59876531; called by muse, mutect2
- WWP2 | c.969C>G p.T323= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV63126331; called by muse, mutect2, varscan2
- ZNF341 | c.966C>G p.L322= (on ENST00000375200 / NM_001282935.1; = p.L315= on NM_032819.4) | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs1418500314, COSV61010225; called by muse, mutect2, varscan2
- ZSCAN21 | c.906G>A p.E302= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV52851724; called by muse, mutect2, varscan2
- GTF2IRD2 | c.-1C>T | 5'UTR (SNP) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- HERC2P3 | chr15:20457676 C>G | 5'Flank (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- IKBIP | c.297+7722G>C | Intron (SNP) | VAF 22/64 reads (34%) | catalogued as COSV54490657; called by muse, mutect2, varscan2
- KLRK1 | c.-1G>C | 5'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as rs371584695; called by muse, mutect2, varscan2
- NIN | chr14:50723567 C>A | 3'Flank (SNP) | VAF 16/82 reads (20%) | catalogued as COSV55392377, COSV99815547; called by muse, mutect2, varscan2
- OBSCN | c.18662-2179G>C | Intron (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- OR52A4P | chr11:5121095 G>T | 3'Flank (SNP) | VAF 11/37 reads (30%) | catalogued as rs770958283; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12786G>C | Intron (SNP) | VAF 20/92 reads (22%) | catalogued as rs1192202043, COSV67447393; called by muse, mutect2, varscan2
- SNORA71E | n.59G>A | RNA (SNP) | VAF 25/160 reads (16%) | catalogued as rs754449410; called by muse, mutect2, varscan2
- TBCE | c.371+4940C>G | Intron (SNP) | VAF 19/84 reads (23%) | catalogued as COSV64006864; called by muse, mutect2, varscan2
- TTN | c.10360+4048G>A | Intron (SNP) | VAF 18/72 reads (25%) | catalogued as COSV60215540; called by muse, mutect2, varscan2
